Somatic mutation profile of tumor specimen MP2PRT-PAVTHK-TMP1-A (aliquot MP2PRT-PAVTHK-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVTHK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,074 days).
Specimen MP2PRT-PAVTHK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7ff6be4-6a8e-4c58-8f8e-f9683b0325f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTHK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTHK-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad6ad2cd-bdd2-415c-984e-7eafa35631cd

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.6910G>A p.A2304T | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.094); catalogued as rs747348765, CM133152, COSV62100084; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 74/291 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDOB | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145252200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRX2 | c.212A>C p.D71A | Missense Mutation (SNP) | VAF 135/649 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs1348131148, COSV57411272; called by muse, mutect2, varscan2
- MCC | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 94/507 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as rs765539734, COSV56738733; called by muse, mutect2, varscan2
- UBE2U | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs747564063, COSV100934568; called by muse, mutect2, varscan2
- GRIA2 | c.1946G>A p.R649K | Missense Mutation (SNP) | VAF 110/475 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HCN1 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 172/804 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, varscan2
- IRF2BP1 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 164/581 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MGAT4C | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 109/392 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- POLR2A | c.454A>T p.N152Y | Missense Mutation (SNP) | VAF 103/398 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZNF540 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A4 | c.3312C>T p.P1104= | Silent (SNP) | VAF 46/202 reads (23%) | catalogued as rs766687694, COSV100710204; called by muse, mutect2, varscan2
- CADPS2 | c.147C>T p.G49= | Silent (SNP) | VAF 169/585 reads (29%) | called by muse, mutect2, varscan2
- MAGEL2 | c.786G>A p.P262= | Silent (SNP) | VAF 144/515 reads (28%) | catalogued as rs772162359; called by muse, varscan2
